Somatic mutation profile of tumor specimen TARGET-15-SJMPAL016343-04A (aliquot TARGET-15-SJMPAL016343-04A-01D) from TARGET case TARGET-15-SJMPAL016343, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,198 days).
Specimen TARGET-15-SJMPAL016343-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea63d844-503c-4550-8394-1777e04139e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL016343-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL016343-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a5cc95d-c2d9-48b8-b502-c69b77b539de

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Intron 3, Silent 2, Frame Shift Ins 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.4110+1G>A p.X1370_splice | Splice Site (SNP) | VAF 43/66 reads (65%) | catalogued as rs1555617383, CS000898, CS971829, COSV62193545, COSV62207614; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACP7 | c.912C>A p.S304R | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as rs909140153; called by muse, mutect2
- GAN | c.146C>A p.A49E | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as CM1310746, COSV73721447; called by muse, mutect2
- CASR | c.763G>A p.V255M | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.349); called by muse, varscan2
- CDH18 | c.2083G>T p.V695L | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.02); called by muse, mutect2
- HMGCR | c.1528C>A p.Q510K | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0.005); called by muse, mutect2
- INPP4B | c.890dup p.N299Kfs*7 | Frame Shift Ins (INS) | VAF 57/133 reads (43%) | called by mutect2, varscan2
- KLHL14 | c.577G>T p.A193S | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- MSX2 | c.207C>A p.S69R | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.044); called by muse, mutect2
- NAIF1 | c.836A>G p.Q279R | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- NUTM1 | c.1151C>A p.A384D | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.031); called by muse, varscan2
- PIK3R4 | c.3798G>T p.R1266S | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRR3 | c.292G>C p.G98R | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- RAB27A | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SPG11 | c.5797G>T p.A1933S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- TMEM109 | c.568C>A p.L190M | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- VANGL1 | c.401C>A p.P134H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- EIF2AK3 | c.132G>T p.A44= | Silent (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2
- MAP3K11 | c.354G>T p.R118= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- AL627230.3 | c.76-99C>T | Intron (SNP) | VAF 20/192 reads (10%) | catalogued as rs1352817288; called by muse, mutect2
- AOC4P | n.613C>A | RNA (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- CD36 | c.120+44C>A | Intron (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- CPSF7 | c.273+245G>A | Intron (SNP) | VAF 43/107 reads (40%) | called by muse, mutect2, varscan2
